Gene-level copy-number profile of tumor specimen TCGA-CV-A6JE-01A from TCGA case TCGA-CV-A6JE, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; Tumor grade: G2; Age at diagnosis: 78.5 years (28,658 days).
Specimen TCGA-CV-A6JE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a88afbe4-41e9-4f89-936d-42971723a6d1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-A6JE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f53e5935-be25-495e-8674-7a182a46c06d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 131; copy number 2: 10,757; copy number 3: 29,015; copy number 4: 12,974; copy number 5: 3,667; copy number 6: 942; copy number 7: 540; copy number 8: 445; copy number 9: 924; copy number 10: 38; copy number 11: 16; copy number 13: 49; copy number 14: 10; copy number 15: 12; copy number 16: 89; copy number 17: 129; copy number 18: 68; copy number 20: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-A6JE-01A-11D-A31K-01): tumor purity 0.47, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:117,262,918–117,264,888, 3 genes: AC006326.1, MTND4P6, MTCYBP6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,323 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,708,931–62,688,386, 604 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr1:64,745,095–66,374,579, 27 genes, copy number 8 (within-gene range 3–8): RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, AL513493.1, RN7SL854P, PDE4B, PDE4B-AS1, RNU4-88P.
- chr1:119,327,399–119,853,748, 24 genes, copy number 7: LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9.
- chr1:219,557,192–221,134,221, 40 genes, copy number 9: AL356364.1, ZC3H11B, SLC30A10, RNA5SP76, U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1, AC096644.3, AC096644.2, AC096644.1, PRELID3BP1, LINC02779, MARK1, RN7SL464P, HDAC1P2, C1orf115, MTARC2, MTARC1, AL445423.3, RNU6ATAC35P, AL445423.2, AL445423.1, LINC01352, HLX-AS1, HLX, AL445466.1.
- chr1:226,045,561–232,041,272, 188 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 9 (broad region; genes not listed).
- chr7:87,152,409–99,576,453, 212 genes, copy number 8–17 (within-gene range 2–17) (broad region; genes not listed).
- chr8:46,028,804–51,015,165, 77 genes, copy number 8–11 (broad region; genes not listed).
- chr8:83,912,713–86,343,429, 48 genes, copy number 10–14: AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1.
- chr8:97,775,057–102,124,907, 106 genes, copy number 9–15 (within-gene range 6–15) (broad region; genes not listed).
- chr8:124,192,671–139,508,971, 183 genes, copy number 8–20 (broad region; genes not listed).
- chr11:68,754,620–71,818,238, 89 genes, copy number 16 (within-gene range 2–16) (broad region; genes not listed).
- chr14:65,410,592–66,509,394, 15 genes, copy number 8: FUT8, FUT8-AS1, RPL21P8, MIR625, EIF1AXP2, NCOA4P1, FTH1P13, AL391261.1, AL391261.2, YBX1P1, LINC02290, Y_RNA, AL359232.1, AL157997.1, CCDC196.

Autosomal genes at a single copy (total copy number 1): 131. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
